Surgical pathology report (de-identified scan), TCGA case TCGA-J8-A3O1, project TCGA-THCA (Thyroid Carcinoma), tissue source site Mayo Clinic, specimen TCGA-J8-A3O1-01A (Primary Tumor).

[page 1 of 4]
FINAL DIAGNOSIS

- A) Left thyroid lobe and isthmus, resection: Papillary carcinoma of thyroid.
(See synoptic checklist)
- B) Left paratracheal tissue, biopsy: Lymph node with metastatic papillary carcinoma of thyroid.
- C) Right paratracheal lymph node, biopsy: Parathyroid tissue present.
- D) Left paratracheal lymph node, biopsy: Three lymph nodes with metastatic papillary carcinoma.
- E) Thyroid, right lobe, resection: Lymphocytic thyroiditis.
- F) Lymph node, central compartment, biopsies: Four of seven lymph nodes positive for metastatic papillary thyroid carcinoma.
- G) Lymph nodes, left lateral jugular, biopsy: Four of eight lymph nodes, positive for metastatic papillary carcinoma.

A: Thyroid Gland

HISTOLOGIC TYPE:

Papillary carcinoma

TUMOR FOCALITY:

Unifocal

ICD-O-3

carcinoma, papillary, thyroid 8260/3

Site: thyroid, NOS C73.9

hw
2/6/12

TUMOR SIZE:

Greatest Dimension: 6.5 cm

HISTOLOGIC GRADE:

G1: Well differentiated

PRIMARY TUMOR (pT):

pT3: Tumor more than 4 cm, limited to thyroid or with minimal extrathyroidal extension (eg, extension to sternothyroid muscle or perithyroid soft tissues)

REGIONAL LYMPH NODES (pN):

pN1b: Metastases to unilateral, bilateral or contralateral cervical (Levels I, II, III, IV, V) or retropharyngeal or superior mediastinal lymph nodes (Level VII).

[page 2 of 4]
NUMBER OF LYMPH NODE(S) INVOLVED: 12

NUMBER OF LYMPH NODE(S) EXAMINED: 19

MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Present:

Focal (less than 4 vessels)

PERINEURAL INVASION:

Not identified

EXTRATHYROIDAL EXTENSION:

Not identified

~electronic signature~

SPECIMEN RECEIVED

- A) LEFT THYROID LOBE AND ISTHMUS, FS
- B) LEFT PARATRACHEAL TISSUE, R/O LYMPH NODE VS PARATHYROID, FS
- C) RIGHT PARATRACHEAL TISSUE, R/O LYMPH NODE VS PARATHYROID, FS
- D) LEFT PARATRACHEAL LYMPH NODE
- E) RIGHT THYROID LOBE
- F) CENTRAL COMPARTMENT LYMPH NODES
- G) LEFT LATERAL JUGULAR LYMPH NODES

FROZEN SECTION

- A) Left thyroid lobe and isthmus, excision: Papillary carcinoma.
- B) Left paratracheal tissue, biopsy: Lymph node with metastatic papillary carcinoma.
Seen with Dr.
- C) Right paratracheal tissue, biopsy: Predominantly fatty tissue with a small fragment of parathyroid gland.

[page 3 of 4]
GROSS DESCRIPTION

- A) Received fresh for frozen section labeled "left thyroid lobe and isthmus" is a lobe of thyroid weighing 55 grams, and measuring 7.0 x 5.5 x 3.5 cm. The red/tan capsular surface appears intact. The specimen is inked with black ink, serially sectioned, and reveals a large dominant nodule which has replaced the majority of the thyroid, measuring approximately 6.5 cm in greatest dimension. A small amount of peripheral red/tan normal thyroid is identified. Representative section of nodule is submitted for frozen section as A1. Touch preps are made from the specimen. Additional sections are submitted for permanent section as follows: A2-A9 additional sections of mass with inked capsule, A10 sections of uninvolved thyroid.
- B) Received fresh for frozen section labeled "left paratracheal tissue" is an irregular portion of pink/tan soft tissue weighing 70 mg, and measuring 0.9 cm in greatest dimension. The specimen is entirely submitted for frozen section as B1.
- C) Received fresh for frozen section labeled "right paratracheal tissue" is an irregular portion of pink/tan soft tissue measuring 0.4 cm in greatest dimension. The specimen weighs 30 mg. The specimen is entirely submitted for frozen section as C1.
- D) In formalin labeled "left paratracheal lymph nodes". The specimen consists of two ovoid portions of pink/tan soft tissue measuring 0.7 and 1.5 cm. The larger specimen is bisected and all three pieces are submitted in cassette D1.
- E) In formalin labeled "right thyroid lobe". The specimen consists of a portion of dark purple/red thyroid tissue measuring 4.0 x 2.5 x 1.0 cm, 6.0 grams. The specimen is inked and serially sectioned revealing dark purple thyroid parenchyma. No suspicious lesions are identified. The specimen is submitted entirely in cassettes E1-E6.
- F) In formalin labeled "central compartment lymph nodes". The specimen consists of an irregular portion of yellow fatty tissue measuring 4.5 x 3.0 x 2.0 cm. The specimen is dissected in search of lymph nodes. Multiple lymph nodes are identified which range in size from 0.5 up to the largest which measures 1.9 cm. Four smaller lymph nodes are submitted whole in cassette F1. A single large lymph node is bisected and submitted in cassette F2. A single lymph node bisected and submitted in F3, a single lymph node bisected and submitted in cassette F4, a single lymph

[page 4 of 4]
node bisected and submitted in F5.

G) In formalin labeled "left lateral jugular lymph nodes". The specimen consists of an irregular portion of pink/tan soft tissue measuring 4.0 x 2.0 x 1.0 cm. The specimen is dissected in search of lymph nodes. Multiple lymph nodes are identified ranging in size from 0.3 up to the largest which measures 1.5 cm. Smaller lymph nodes are submitted whole in cassette G1, the larger lymph node is bisected and submitted entirely in cassette G2.

CLINICAL INFORMATION

THYROID CANCER

Primary Malignancy History		/

Source: NCI Genomic Data Commons file 396ca676-0593-43f4-912a-ab5652f9e53b (TCGA-J8-A3O1.08ABFE9F-B5B1-49F3-907A-7E9BF2556180.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).